Gene-level copy-number profile of tumor specimen TCGA-22-4613-01A from TCGA case TCGA-22-4613, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 73.2 years (26,722 days).
Specimen TCGA-22-4613-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.bd85099a-b246-474d-a356-b5b2ffb0d530.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-4613-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f7663372-a3c5-44d6-8949-609c0692ccb4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 19,604; copy number 2: 31,526; copy number 3: 5,051; copy number 4: 1,602; copy number 5: 587; copy number 6: 138; copy number 7: 1,089; copy number 8: 158; copy number 9: 2; copy number 10: 12; copy number 11: 30; copy number 13: 2; copy number 14: 11; copy number 15: 4; copy number 24: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-4613-01A-01D-1439-01): tumor purity 0.62, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,035 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:60,057,601–64,863,626, 117 genes, copy number 6–15 (broad region; genes not listed).
- chr2:64,906,863–64,907,138, 1 gene, copy number 6: RN7SL211P.
- chr2:82,814,984–87,013,976, 96 genes, copy number 5 (broad region; genes not listed).
- chr2:95,297,327–98,398,601, 111 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr2:100,370,255–100,747,391, 14 genes, copy number 7: CYCSP7, AC012493.1, CHST10, RALBP1P2, NMS, ARPP19P2, PDCL3, HMGN2P22, LINC01849, AC092845.1, NANOGNBP1, LINC01868, AC092168.1, AC092168.3.
- chr2:100,822,661–100,847,220, 1 gene, copy number 7 (within-gene range 2–7): AC092168.2.
- chr2:183,117,513–183,495,501, 4 genes, copy number 9–24 (within-gene range 1–24): NUP35, AC021851.1, AC021851.2, LIN28AP1.
- chr3:120,684,938–120,908,093, 8 genes, copy number 6 (within-gene range 4–6): RABL3, MTCO1P29, MTCO2P29, GTF2E1, NAP1L1P3, AC072026.2, LINC02049, AC072026.3.
- chr3:141,115,124–143,060,725, 50 genes, copy number 5: AC108727.2, PXYLP1, AC022215.2, AC022215.1, AC117383.1, AC117383.2, ZBTB38, AC010184.1, KRT18P35, RASA2, RASA2-IT1, YWHAQP6, LINC02618, TPT1P3, AC112771.1, RNF7, AC112504.2, GRK7, AC112504.3, HMGN2P25, ATP1B3, RNU6-509P, ATP1B3-AS1, AC112504.1, TFDP2, AC133435.1, RNU6-425P, GK5, XRN1, RNU6-1294P, RNU1-100P, ATR, AC109992.1, AC109992.2, RPL6P9, RNA5SP143, PLS1, PLS1-AS1, RN7SKP25, AC072028.1, TRPC1, RNU7-47P, PCOLCE2, AC021074.1, AC021074.3, PAQR9, AC021074.2, PAQR9-AS1, U2SURP, AC026304.1.
- chr3:143,855,739–198,222,513, 937 genes, copy number 5–7 (broad region; genes not listed).
- chr4:67,468,762–68,304,939, 27 genes, copy number 5: CENPC, STAP1, AC096720.2, UBA6, AC096720.1, UBA6-AS1, ST3GAL1P1, AC079880.1, AC079880.2, GNRHR, SNORA62, TMPRSS11CP, TMPRSS11D, TMPRSS11A, TMPRSS11GP, RNU6-95P, GCOM2, MTND2P41, TMPRSS11F, SYT14P1, FTLP10, TMPRSS11BNL, TMPRSS11B, AC098799.3, AC098799.1, AC098799.2, APOOP4.
- chr5:41,306,952–45,895,970, 73 genes, copy number 5–6 (broad region; genes not listed).
- chr9:33,524,394–35,907,136, 135 genes, copy number 5 (broad region; genes not listed).
- chr10:83,067,962–84,153,568, 11 genes, copy number 10 (within-gene range 1–10): RNU6-478P, MARK2P15, LINC02650, AC069540.2, AC069540.1, RNU6-129P, AL390786.1, RNU1-65P, HMGN2P8, AL603756.1, GHITM.
- chr13:21,628,413–21,704,498, 2 genes, copy number 13: RPS7P10, FGF9.
- chr14:37,197,913–37,596,059, 5 genes, copy number 5 (within-gene range 3–5): MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1.
- chr17:33,013,087–34,174,964, 1 gene, copy number 5 (within-gene range 2–6): ASIC2.
- chr17:33,529,787–35,089,319, 38 genes, copy number 5–6 (within-gene range 3–6): AA06, AC011824.3, AC011824.2, AC011824.1, AC024614.1, AC024614.2, AC024614.3, AC024614.4, AC024610.2, AC004147.4, AC024610.1, AC123769.1, TLK2P1, AC004147.1, AC004147.5, RNA5SP438, AC004147.3, AC004147.2, LINC01989, AC005549.1, CCL2, CCL7, CCL11, CCL8, AC011193.2, CCL13, CCL1, AC011193.1, C17orf102, TMEM132E, AC005691.1, AC005552.1, AC022903.1, CCT6B, AC022903.2, ZNF830, LIG3, RFFL.
- chr17:35,018,660–35,018,991, 1 gene, copy number 6: AC004223.4.
- chr17:37,375,985–37,613,841, 8 genes, copy number 5: C17orf78, AC243654.3, TADA2A, AC243654.1, AC243654.2, DUSP14, SYNRG, AC243585.2.
- chr17:37,614,931–37,615,039, 1 gene, copy number 5: MIR378J.
- chr18:20,946,906–49,461,347, 394 genes, copy number 7–14 (within-gene range 1–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 17,912. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
